Somatic mutation profile of tumor specimen 0DPFMJ from CCDI case PBCDDX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,839 days).
Specimen 0DPFMJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5f8cab3-b3ff-4795-859f-da83fbad3853.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPFM9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b340356f-3309-4146-b5bf-164a404c5ba8

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 255/692 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 168/504 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARL6IP5 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 170/626 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV56235166; called by muse, varscan2
- CEP43 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 175/576 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs377028909, COSV62760903; called by muse, mutect2, varscan2
- NDUFS7 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 87/238 reads (37%) | catalogued as COSV52039653; called by muse, mutect2, varscan2
- PSG9 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 180/297 reads (61%) | catalogued as rs527502595, COSV52486504; called by muse, mutect2, varscan2
- RIPOR3 | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50388039; called by muse, mutect2, varscan2
- TPSB2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs762514060, COSV52353096; called by muse, mutect2
- ZNF480 | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 186/663 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100574363; called by muse, varscan2
- CD1D | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 56/900 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2
- CLPTM1L | c.1110G>C p.M370I | Missense Mutation (SNP) | VAF 180/697 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.360_363del p.L121Tfs*43 | Frame Shift Del (DEL) | VAF 417/731 reads (57%) | called by mutect2, varscan2*
- PLCXD3 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 161/950 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DAOA | c.225G>A p.R75= | Silent (SNP) | VAF 190/713 reads (27%) | catalogued as COSV100298897; called by muse, mutect2, varscan2
- ENTR1 | c.612C>T p.G204= (on ENST00000357365 / NM_001039707.2; = p.G181= on NM_006643.4) | Silent (SNP) | VAF 138/441 reads (31%) | called by muse, mutect2, varscan2
- ITGA8 | c.2274C>T p.F758= | Silent (SNP) | VAF 229/836 reads (27%) | catalogued as rs764265512, COSV65229014; called by muse, mutect2, varscan2
- RYR2 | c.6279C>T p.D2093= | Silent (SNP) | VAF 330/762 reads (43%) | catalogued as rs771328006, COSV63661917; ClinVar: likely benign; called by muse, mutect2, varscan2
- STK33 | c.807G>C p.A269= | Silent (SNP) | VAF 50/593 reads (8%) | catalogued as COSV59396639; called by muse, mutect2
- C1orf167 | c.3921-11C>T | Intron (SNP) | VAF 59/369 reads (16%) | catalogued as rs762678203; called by muse, mutect2, varscan2
- CYP8B1 | c.-32G>A | 5'UTR (SNP) | VAF 43/203 reads (21%) | catalogued as rs371120917; called by muse, mutect2, varscan2
- SHANK2 | c.1174+53A>C | Intron (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
